TARGET case TARGET-40-NAAHBY — Osteosarcoma (TARGET-OS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Osseous and Chondromatous Neoplasms; Primary site: Bones, joints and articular cartilage of limbs. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/17a8af6f-3aae-5f9a-aeed-8855fa54b055

Demographics
Sex at birth: female; Age at index: 15 years; Vital status: Dead; Days to death: 851 days (2.3 years).

Diagnoses (1)
1. Osteosarcoma, NOS: ICD-O-3 morphology code: 9180/3; ICD-10 code: C40.0; Tissue or organ of origin: Long bones of upper limb, scapula and associated joints; Laterality: Right; Classification of tumor: primary; Age at diagnosis: 15.2 years (5,538 days); Year of diagnosis: 2001; Metastasis at diagnosis: No Metastasis; Days to last follow up: 851 days (2.3 years).
   Pathology details: Necrosis percent: 85.
   Treatment given: Protocol identifier: BCM.

Follow-up (2 entries)
- Days to follow up: 284 days; Progression or recurrence: Yes; Progression or recurrence anatomic site: Long bones of upper limb, scapula and associated joints; Days to progression: 284 days; Days to first event: 284 days; First event: Relapse.
- Days to follow up: 851 days (2.3 years); Progression or recurrence: Yes; Progression or recurrence type: Local; Year of follow up: 2003.

Biospecimens (3 samples)
- Sample TARGET-40-NAAHBY-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
- Sample TARGET-40-NAAHBY-02A: Sample type: Recurrent Tumor; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Solid Tissue.
- Sample TARGET-40-NAAHBY-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the TARGET clinical supplement workbook TARGET_OS_ClinicalData_Validation_20230329.xlsx (sheet Clinical Data):
- Overall Survival Time in Days: 851
- Protocol: BCM
- Disease at diagnosis: Non-metastatic
- Primary tumor site: Arm/hand
- Specific tumor site: Humerus
- Specific tumor region: Proximal
- Primary site progression: Yes
- Site of initial relapse: Right shoulder
- Histologic response: Stage 1/2 (0-90 % necrosis)
